CPTAC case C3N-00310 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f344e9f-478a-40a2-99c9-3435fd0b9bbe

Demographics
Sex at birth: male; Race: white; Year of birth: 1931; Vital status: Dead; Days to death: 1,623 days (4.4 years); Year of death: 2020; Cause of death: Infection; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 84.9 years (31,016 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,623 days (4.4 years); Progression or recurrence: no; Days to last follow up: 1,623 days (4.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 395 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 759 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,187 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 1,387 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,622 days (4.4 years); Disease response: Complete Response; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 1,623 days (4.4 years); Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 84 kg; Height: 172 cm; BMI: 28.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 1; Cigarettes per day: 10; Tobacco smoking onset year: 1951; Tobacco smoking quit year: 1953; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 2.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00310-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 723 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00310-21: Section location: Middle; Percent tumor nuclei: 80; Percent necrosis: 20.
- Sample C3N-00310-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 460 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00310-22: Section location: Middle; Percent tumor nuclei: 65; Percent necrosis: 25.
- Sample C3N-00310-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 498 mg; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00310-23: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-00310-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 375 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00310-24: Section location: Middle; Percent tumor nuclei: 75; Percent necrosis: 30.
- Sample C3N-00310-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 507 mg; Time between excision and freezing: 14 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00310-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
